Somatic mutation profile of tumor specimen ALCH-ADZZ-TTP1-A (aliquot ALCH-ADZZ-TTP1-A-1-0-D-A603-36) from ALCHEMIST case ALCH-ADZZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.3 years (28,244 days).
Specimen ALCH-ADZZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3723f911-facc-40e1-a0df-9e34d5a7f4c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADZZ-NB1-A (Blood Derived Normal), aliquot ALCH-ADZZ-NB1-A-1-0-D-A603-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2ba848a-a030-4647-87c7-420b1062eb12

The open-access MAF lists 525 somatic variants for this specimen: 367 protein-altering or splice-affecting, 104 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 104, Nonsense Mutation 33, Intron 27, Splice Site 8, 5'UTR 7, RNA 7, 5'Flank 5, 3'UTR 4, 3'Flank 3, Frame Shift Del 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 54/528 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTR1B | c.725C>T p.T242M | Missense Mutation (SNP) | VAF 50/546 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs769045495; called by muse, mutect2
- AGMO | c.823-1G>T p.X275_splice | Splice Site (SNP) | VAF 13/126 reads (10%) | catalogued as rs1468187581; called by muse, mutect2
- ANKLE2 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 44/672 reads (7%) | catalogued as COSV61708932, COSV61710413; called by muse, mutect2
- AP2S1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV99617391; called by muse, mutect2
- ASH1L | c.5554C>T p.R1852* | Nonsense Mutation (SNP) | VAF 26/386 reads (7%) | catalogued as COSV64209234; called by muse, mutect2
- ATL2 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 50/540 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100185080; called by muse, mutect2
- BICDL2 | c.556C>G p.Q186E | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs777728130, COSV99560806; called by muse, mutect2, varscan2
- BNC1 | c.2758G>C p.A920P | Missense Mutation (SNP) | VAF 49/757 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as rs1248240947, COSV61756906; called by muse, mutect2
- C16orf71 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 53/440 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs755789871; called by muse, varscan2
- C1orf162 | c.311C>G p.S104* | Nonsense Mutation (SNP) | VAF 21/412 reads (5%) | catalogued as rs1557809618; called by muse, mutect2
- CACNA1B | c.1982C>A p.T661K | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53134349; called by muse, mutect2
- CACNA1C | c.2614G>C p.V872L | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as COSV59710475; called by muse, mutect2
- CALD1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 60/398 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100724214, COSV62646234; called by muse, mutect2, varscan2
- CAMK1G | c.726C>G p.F242L | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV50523432; called by muse, mutect2
- CAPSL | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV101274266; called by muse, mutect2
- CARMIL1 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as COSV61513208; called by muse, mutect2
- CCR8 | c.265C>G p.P89A | Missense Mutation (SNP) | VAF 32/449 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58336647; called by muse, mutect2
- CD1D | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 185/876 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1298885559, COSV63808859; called by muse, mutect2, varscan2
- CELA2B | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 48/510 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as rs751797790, COSV65546054; called by muse, mutect2
- CFAP47 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV52887323; called by muse, mutect2
- CFAP65 | c.4222C>A p.H1408N | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV100446095; called by muse, mutect2
- CLGN | c.998+1G>A p.X333_splice | Splice Site (SNP) | VAF 14/140 reads (10%) | catalogued as COSV100346987; called by muse, mutect2
- CNTN3 | c.2942G>C p.G981A | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55188401; called by muse, mutect2
- CT47B1 | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 95/1059 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.765); catalogued as COSV100988953; called by muse, mutect2
- CUTC | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.413); catalogued as COSV65081890; called by muse, mutect2
- DACT1 | c.917G>C p.C306S | Missense Mutation (SNP) | VAF 60/698 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV60023827; called by muse, mutect2
- DCC | c.3277C>T p.Q1093* | Nonsense Mutation (SNP) | VAF 76/1158 reads (7%) | catalogued as COSV101473256; called by muse, mutect2
- DHX57 | c.1978C>T p.Q660* | Nonsense Mutation (SNP) | VAF 35/286 reads (12%) | catalogued as rs901409167; called by muse, varscan2
- DNAJC6 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 36/540 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54772281, COSV54775041; called by muse, mutect2
- DOP1B | c.6436C>T p.L2146F | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774609126; called by muse, mutect2
- EML6 | c.563G>C p.R188T | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.765); catalogued as rs1558584119; called by muse, mutect2
- ERBIN | c.1067A>T p.K356I | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52321975; called by muse, mutect2
- FBF1 | c.74G>T p.R25I (on ENST00000586717; = p.R39I on NM_001319193.1) | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100045262; called by muse, mutect2
- FEZF2 | c.930C>A p.C310* | Nonsense Mutation (SNP) | VAF 29/259 reads (11%) | catalogued as COSV51862338; called by muse, mutect2, varscan2
- FOXD4L1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1395522944; called by muse, mutect2, varscan2
- GAD2 | c.1739G>T p.R580L | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.691); catalogued as COSV52162140; called by muse, mutect2
- GRIK1 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 12/275 reads (4%) | catalogued as COSV100516902, COSV100517734, COSV58711969; called by muse, mutect2
- GRK6 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62682576; called by muse, mutect2
- HOXA2 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 133/1087 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV56065751; called by muse, mutect2, varscan2
- HRNR | c.3218C>T p.S1073F | Missense Mutation (SNP) | VAF 271/1933 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.94); catalogued as rs766728830; called by muse, mutect2, varscan2
- ICA1L | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 60/705 reads (9%) | catalogued as rs764157511, COSV100841623; called by muse, mutect2
- ISM2 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); catalogued as COSV53633899; called by muse, mutect2, varscan2
- KAT6A | c.5206C>T p.P1736S | Missense Mutation (SNP) | VAF 25/246 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV55910250; called by muse, mutect2, varscan2
- KAT6A | c.5101C>G p.P1701A | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs539376929, COSV99064604; called by muse, mutect2, varscan2
- KCNQ1 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 58/550 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.923); catalogued as CM960895, CM970818; called by muse, mutect2, varscan2
- KPRP | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 42/614 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100908795, COSV64221232; called by muse, mutect2
- LPAR1 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62690346; called by muse, mutect2
- LRFN5 | c.104C>A p.T35N | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53242758; called by muse, mutect2
- LRP1B | c.3483G>T p.K1161N | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV67190154; called by muse, mutect2, varscan2
- MAS1 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 44/518 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV53120830; called by muse, mutect2
- MATK | c.953C>A p.T318N (on ENST00000310132 / NM_139355.3; = p.T319N on NM_002378.4) | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1468742302; called by muse, mutect2
- MECP2 | c.830C>A p.A277E | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as CD032744; called by muse, mutect2
- MEGF6 | c.3522G>A p.M1174I | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1005532219; called by muse, mutect2
- MON1A | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.66); catalogued as rs778489301; called by muse, mutect2
- MYH8 | c.5095G>T p.E1699* | Nonsense Mutation (SNP) | VAF 72/1085 reads (7%) | catalogued as COSV67973750; called by muse, mutect2
- MYMK | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.967); catalogued as rs769380725, COSV60600782; called by muse, mutect2, varscan2
- NLRP3 | c.1242G>C p.W414C | Missense Mutation (SNP) | VAF 32/471 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60224039; called by muse, mutect2
- NMRK2 | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 39/459 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs751214143; called by muse, mutect2
- NMUR2 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 41/542 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54919195; called by muse, mutect2
- NPAP1 | c.3176G>T p.W1059L | Missense Mutation (SNP) | VAF 37/563 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as COSV61507548; called by muse, mutect2
- NUP188 | c.1750G>C p.D584H | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101001522; called by muse, mutect2
- NUPR1 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV61405021; called by muse, mutect2
- OCA2 | c.149C>G p.S50C | Missense Mutation (SNP) | VAF 50/666 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.43); catalogued as rs549983090; called by muse, mutect2
- OGDH | c.2562A>T p.L854F | Missense Mutation (SNP) | VAF 41/400 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99759020; called by muse, mutect2, varscan2
- OR11H12 | c.225C>A p.Y75* | Nonsense Mutation (SNP) | VAF 24/662 reads (4%) | catalogued as COSV99081853; called by muse, mutect2
- OR2T1 | c.693G>T p.E231D | Missense Mutation (SNP) | VAF 25/365 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV100822265, COSV63542900; called by muse, mutect2
- OR6Y1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 110/538 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100225560; called by muse, mutect2, varscan2
- PAX2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 43/536 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100694998; called by muse, mutect2
- PCDH15 | c.5000C>A p.A1667E | Missense Mutation (SNP) | VAF 38/487 reads (8%) | SIFT deleterious, low confidence (0); catalogued as COSV100905297; called by muse, mutect2
- PCDHGA3 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1465653147; called by muse, mutect2
- PCDHGB3 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV99547362; called by muse, mutect2
- PEG3 | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55637343, COSV99687906; called by muse, mutect2
- PGM1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 31/353 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); catalogued as rs765829037; called by muse, mutect2
- PLOD2 | c.1852C>G p.L618V | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV51466263; called by muse, mutect2
- PLXNB2 | c.5116G>A p.E1706K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs1433328187; called by muse, mutect2, varscan2
- PNLIPRP3 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV100982485; called by muse, mutect2
- POLDIP2 | c.243+1G>T p.X81_splice | Splice Site (SNP) | VAF 28/360 reads (8%) | catalogued as COSV50228129; called by muse, mutect2
- POLR3B | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 50/691 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99943282; called by muse, mutect2
- PRPF40A | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.916); catalogued as rs1407766011; called by muse, mutect2
- PTPA | c.1067C>T p.T356M (on ENST00000337738 / NM_178001.2; = p.T321M on NM_021131.5) | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs150059994; called by muse, mutect2
- QARS1 | c.1991C>T p.T664I | Missense Mutation (SNP) | VAF 23/365 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs140225766; called by muse, mutect2
- RELN | c.1754C>A p.P585H | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58988529; called by muse, mutect2, varscan2
- SERPINA4 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751574089; called by muse, mutect2
- SHISA9 | c.813A>T p.K271N | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV69637722; called by muse, mutect2
- SIGLEC1 | c.4501G>A p.V1501M | Missense Mutation (SNP) | VAF 56/666 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs781542845; called by muse, mutect2
- SLC25A13 | c.1327G>A p.V443M | Missense Mutation (SNP) | VAF 104/765 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485527456; called by muse, mutect2, varscan2
- SLC35E3 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57494315; called by muse, varscan2
- SMR3B | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV59228511, COSV59228626; called by muse, mutect2
- SNTG1 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 48/686 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV52442516; called by muse, mutect2
- SORBS2 | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144923775, COSV53003719; called by muse, mutect2
- SPATA18 | c.243G>T p.W81C | Missense Mutation (SNP) | VAF 23/497 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54641719; called by muse, mutect2
- SPEN | c.9853C>A p.P3285T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV101005624, COSV65367910; called by muse, mutect2, varscan2
- STK32B | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV99286284; called by muse, mutect2, varscan2
- SVIL | c.6059A>T p.Y2020F (on ENST00000355867 / NM_021738.3; = p.Y1594F on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/670 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV63440820; called by muse, mutect2
- SYNJ2 | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 38/634 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs771454251, COSV100840664; called by muse, mutect2
- SYTL2 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 34/417 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1452117759; called by muse, mutect2
- TACC2 | c.2005G>T p.V669F | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs867958572; called by muse, mutect2
- TBX22 | c.1448C>A p.S483Y | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV64785466, COSV64786905, COSV64787241; called by muse, mutect2
- TDRD5 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1216369123; called by muse, mutect2, varscan2
- TENM1 | c.691G>C p.A231P | Missense Mutation (SNP) | VAF 33/496 reads (7%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.092); catalogued as rs767893601, COSV64438242; called by muse, mutect2
- TIGD2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 20/377 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs1303305701, COSV57648672; called by muse, mutect2
- TMEM44 | c.1327G>A p.E443K (on ENST00000392432 / NM_001166305.2; = p.E406K on NM_138399.5) | Missense Mutation (SNP) | VAF 26/401 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as rs777678143; called by muse, mutect2
- TRPC5OS | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 25/409 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99460154; called by muse, mutect2
- TRPV3 | c.956G>C p.R319P | Missense Mutation (SNP) | VAF 52/747 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as rs151284467, COSV56788480; called by muse, mutect2
- TSC2 | c.1654G>T p.A552S | Missense Mutation (SNP) | VAF 40/519 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs777121421, COSV54756014; called by muse, mutect2
- TSHB | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 30/469 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV56655235; called by muse, mutect2
- TTN | c.68830G>A p.E22944K (on ENST00000591111; = p.E15520K on NM_003319.4) | Missense Mutation (SNP) | VAF 22/217 reads (10%) | PolyPhen probably damaging (0.99); catalogued as COSV100593357; called by muse, mutect2
- TUBB4B | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.241); catalogued as COSV61117162; called by muse, mutect2
- TUBB8B | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs1374293069, COSV58268122; called by muse, mutect2
- WNK4 | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53821714; called by muse, mutect2
- ZNF208 | c.1487C>A p.P496H | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV101236721; called by muse, mutect2
- ZNF257 | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV101448017, COSV71310914; called by muse, mutect2
- ZNF750 | c.384G>C p.Q128H | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV53959732; called by muse, mutect2, varscan2
- ZP4 | c.1111C>A p.P371T | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV63913123; called by muse, mutect2
- ZSWIM6 | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53172134; called by muse, mutect2
- ADAMTS10 | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ADD2 | c.272C>A p.A91E | Missense Mutation (SNP) | VAF 62/498 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ADGRD2 | c.1780C>A p.Q594K | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.46); called by muse, mutect2
- AFF2 | c.1358A>T p.Q453L | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2
- AFF3 | c.385A>T p.T129S | Missense Mutation (SNP) | VAF 133/1042 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFG1L | c.51C>A p.S17R | Missense Mutation (SNP) | VAF 59/485 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK | c.7796T>C p.V2599A | Missense Mutation (SNP) | VAF 31/457 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); called by muse, mutect2
- AIM2 | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 26/590 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.396); called by muse, mutect2
- ALDH16A1 | c.1010A>G p.D337G | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- ALMS1 | c.12345G>C p.M4115I | Missense Mutation (SNP) | VAF 53/843 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- ALOX15 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 51/580 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.275); called by muse, mutect2
- AMOTL1 | c.1716G>T p.E572D | Missense Mutation (SNP) | VAF 38/497 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2
- ANGPTL1 | c.1421G>C p.R474T | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2
- ANKRD12 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKRD37 | c.13G>C p.D5H | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- ANKS1B | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- AR | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 28/351 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.945); called by muse, mutect2
- ARHGAP6 | c.1582A>G p.I528V | Missense Mutation (SNP) | VAF 56/804 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- ARHGEF33 | c.671A>T p.K224M | Missense Mutation (SNP) | VAF 58/932 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- ASB9 | c.532C>G p.Q178E | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.226); called by muse, mutect2
- ASCL4 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 39/372 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ASXL3 | c.4831G>A p.D1611N | Missense Mutation (SNP) | VAF 30/508 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); called by muse, mutect2
- ATG2A | c.3784G>T p.E1262* | Nonsense Mutation (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- ATP6V1C2 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- BTNL9 | c.929-1G>T p.X310_splice | Splice Site (SNP) | VAF 64/746 reads (9%) | called by muse, mutect2
- C16orf71 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, varscan2
- C1QTNF7 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2
- C2orf66 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CCDC68 | c.222A>T p.Q74H | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); called by muse, mutect2
- CCDC86 | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 28/435 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2
- CCT6A | c.284A>C p.N95T | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2
- CD1A | c.833del p.C278Ffs*3 | Frame Shift Del (DEL) | VAF 46/251 reads (18%) | called by mutect2, pindel, varscan2
- CDC14C | c.750C>A p.C250* (on ENST00000428251; = p.C143* on NM_152627.3) | Nonsense Mutation (SNP) | VAF 36/318 reads (11%) | called by muse, varscan2
- CDH5 | c.811A>T p.T271S | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.026); called by muse, mutect2
- CDK7 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 47/678 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- CEP152 | c.2150C>G p.S717C | Missense Mutation (SNP) | VAF 34/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CEP192 | c.4538_4539insT p.G1514Rfs*20 | Frame Shift Ins (INS) | VAF 27/242 reads (11%) | called by mutect2, pindel, varscan2
- CEP350 | c.4792+1G>T p.X1598_splice | Splice Site (SNP) | VAF 42/246 reads (17%) | called by muse, mutect2, varscan2
- CERS3 | c.607A>T p.K203* | Nonsense Mutation (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2
- CFAP54 | c.7035G>T p.Q2345H | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.346); called by muse, mutect2
- CHRNA4 | c.1327C>A p.H443N | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.054); called by muse, mutect2
- CHRNG | c.143C>G p.S48W | Missense Mutation (SNP) | VAF 37/836 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- CIZ1 | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 31/350 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- CMTM5 | c.656A>T p.Q219L (on ENST00000339180 / NM_001288746.2; = p.Q152L on NM_138460.3) | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- CMTR2 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- COA8 | c.255A>C p.K85N | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.316); called by muse, mutect2
- CPXM2 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.5015A>T p.Q1672L (on ENST00000520002; = p.Q1671L on NM_033225.6) | Missense Mutation (SNP) | VAF 24/341 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- D2HGDH | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2
- DAZAP1 | c.146A>T p.Q49L | Missense Mutation (SNP) | VAF 24/424 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2
- DCAF8L2 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 51/585 reads (9%) | called by muse, mutect2
- DCHS1 | c.6160A>T p.I2054F | Missense Mutation (SNP) | VAF 42/555 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- DEFB110 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DENND4C | c.5123C>T p.S1708L (on ENST00000434457 / NM_001330640.2; = p.S1659L on NM_017925.7) | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- DHTKD1 | c.2174A>C p.E725A | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2
- DHX15 | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.272); called by muse, mutect2
- DIAPH2 | c.2819A>T p.H940L | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- DIPK1C | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2
- DNAH12 | c.5002A>T p.T1668S (on ENST00000351747; = p.T1691S on NM_001366028.2) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DPF3 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- DSG4 | c.25A>T p.I9F | Missense Mutation (SNP) | VAF 32/467 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- DYNC1H1 | c.2564A>G p.E855G | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- EFCAB5 | c.3277T>A p.S1093T | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.053); called by muse, mutect2
- EPHA8 | c.1937C>A p.S646Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2
- EVC2 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- F13A1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 51/359 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- FAM114A1 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM135B | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- FAM20C | c.1665G>T p.K555N | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- FAM71C | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 59/784 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- FGFBP2 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FIBCD1 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- FLNC | c.1282del p.L428Wfs*64 | Frame Shift Del (DEL) | VAF 34/354 reads (10%) | called by mutect2, pindel
- FMO6P | n.947+1G>A | Splice Site (SNP) | VAF 19/298 reads (6%) | called by muse, mutect2
- FOXO4 | c.603C>A p.S201R | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2
- FRMPD1 | c.3682G>T p.A1228S | Missense Mutation (SNP) | VAF 38/489 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); called by muse, mutect2
- FRY | c.4919G>T p.C1640F | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- FSCB | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.078); called by muse, mutect2
- FSHR | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 61/423 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.15340C>A p.P5114T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- FUBP1 | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GABRA4 | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- GAL3ST2 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 51/409 reads (12%) | called by muse, mutect2, varscan2
- GNE | c.1951G>A p.E651K (on ENST00000396594 / NM_001128227.3; = p.E620K on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/1038 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.453); called by muse, mutect2
- GPATCH2 | c.1453G>T p.G485C | Missense Mutation (SNP) | VAF 72/972 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPX6 | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 53/348 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GRM6 | c.898C>A p.H300N | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, mutect2
- GTF2I | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- HHLA2 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- HOXA10 | c.172T>A p.Y58N | Missense Mutation (SNP) | VAF 70/668 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IGDCC4 | c.2572C>A p.P858T | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.959); called by muse, mutect2
- IPO13 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 38/446 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2
- IQSEC2 | c.2503G>A p.D835N (on ENST00000642864 / NM_001111125.3; = p.D630N on NM_015075.2) | Missense Mutation (SNP) | VAF 52/707 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- ITGAX | c.3319C>A p.P1107T | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2
- KCNC1 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- KDM4C | c.2974A>G p.K992E | Missense Mutation (SNP) | VAF 29/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KLF12 | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 25/474 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KRT27 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 74/1100 reads (7%) | called by muse, mutect2
- KRT35 | c.1071C>G p.C357W | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); called by muse, mutect2
- KRT79 | c.229G>T p.G77* | Nonsense Mutation (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2
- KRTAP13-2 | c.203C>A p.T68K | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.93); called by muse, mutect2
- LAMB1 | c.4807G>A p.E1603K | Missense Mutation (SNP) | VAF 34/628 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2
- LAMB3 | c.3223C>T p.Q1075* | Nonsense Mutation (SNP) | VAF 42/618 reads (7%) | called by muse, mutect2
- LARP4 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 36/492 reads (7%) | called by muse, mutect2
- LDB2 | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- LHX9 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 50/792 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LMO4 | c.422G>C p.R141T | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.229); called by muse, mutect2
- LPAR6 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 31/481 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.328); called by muse, mutect2
- LRP1B | c.6171T>A p.C2057* | Nonsense Mutation (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- LRP1B | c.4067T>G p.L1356R | Missense Mutation (SNP) | VAF 56/492 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.3843T>A p.S1281R | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRP1B | c.2948G>A p.S983N | Missense Mutation (SNP) | VAF 27/328 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- LSAMP | c.128T>A p.V43E | Missense Mutation (SNP) | VAF 61/998 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- LTBP1 | c.3578A>T p.Q1193L (on ENST00000404816 / NM_206943.4; = p.Q867L on NM_000627.4) | Missense Mutation (SNP) | VAF 45/359 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MAGEB4 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- MAMLD1 | c.877C>G p.L293V | Missense Mutation (SNP) | VAF 62/628 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- MAPK8IP1 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2
- MARCHF7 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); called by muse, mutect2
- MEF2C | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 60/656 reads (9%) | called by muse, mutect2
- MPHOSPH8 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 100/1234 reads (8%) | called by muse, mutect2
- MRPS9 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MTUS2 | c.2282G>T p.R761L | Missense Mutation (SNP) | VAF 52/802 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC17 | c.8963C>T p.P2988L | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MYH3 | c.5727A>T p.E1909D | Missense Mutation (SNP) | VAF 49/671 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MYO10 | c.1460T>C p.I487T | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYOZ2 | c.316T>A p.L106M | Missense Mutation (SNP) | VAF 44/800 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- NAGPA | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 142/941 reads (15%) | PolyPhen benign (0.365); called by muse, mutect2, varscan2
- NBEA | c.1327A>G p.I443V | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.103); called by muse, mutect2
- NDST4 | c.559A>T p.N187Y | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- NDUFB11 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2
- NEB | c.10702T>G p.W3568G | Missense Mutation (SNP) | VAF 80/1168 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.149); called by muse, mutect2
- NEURL1 | c.1601A>T p.Y534F | Missense Mutation (SNP) | VAF 66/640 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, varscan2
- NEXMIF | c.2497T>G p.F833V | Missense Mutation (SNP) | VAF 29/403 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NFATC4 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 45/329 reads (14%) | called by muse, mutect2, varscan2
- NLRP4 | c.888C>G p.I296M | Missense Mutation (SNP) | VAF 44/509 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.938); called by muse, mutect2
- NOS2 | c.1601C>A p.A534E | Missense Mutation (SNP) | VAF 50/445 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- NR2F6 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- NUAK2 | c.1714G>C p.V572L | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.284); called by mutect2, varscan2
- NUP188 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 29/422 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2
- OR10J5 | c.809A>T p.D270V | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10K2 | c.300A>T p.Q100H | Missense Mutation (SNP) | VAF 49/740 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- OR13C3 | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2
- OR1C1 | c.832T>A p.Y278N | Missense Mutation (SNP) | VAF 26/497 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR4K5 | c.851C>G p.P284R | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR4M1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, mutect2
- OR5R1 | c.607G>C p.A203P | Missense Mutation (SNP) | VAF 14/385 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR6C4 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2
- PAPPA2 | c.3532G>T p.D1178Y | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PARP9 | c.372A>C p.K124N | Missense Mutation (SNP) | VAF 34/421 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- PCDH12 | c.2679C>A p.D893E | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB6 | c.1193T>A p.F398Y | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.696); called by muse, mutect2
- PCNT | c.5605A>T p.T1869S | Missense Mutation (SNP) | VAF 48/736 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- PCNT | c.6055G>T p.V2019L | Missense Mutation (SNP) | VAF 89/838 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDCD11 | c.4342G>T p.E1448* | Nonsense Mutation (SNP) | VAF 40/548 reads (7%) | called by muse, mutect2
- PDE3A | c.1487C>A p.S496Y | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2
- PDE8B | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 64/1078 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PDZD3 | c.1257G>C p.M419I (on ENST00000531114; = p.M339I on NM_024791.4) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PGK2 | c.650T>A p.V217E | Missense Mutation (SNP) | VAF 52/572 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHLPP1 | c.1889A>T p.Q630L | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2
- PLEC | c.4404C>G p.S1468R (on ENST00000322810 / NM_201380.4; = p.S1358R on NM_000445.5) | Missense Mutation (SNP) | VAF 59/748 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- PLPPR4 | c.1562G>C p.R521T | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PNMA3 | c.1080C>G p.I360M | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2
- PPEF1 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- PPP4R3C | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 49/558 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.249); called by muse, mutect2
- PRDM9 | c.2462G>T p.R821I | Missense Mutation (SNP) | VAF 213/1206 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PROSER3 | c.1120G>T p.G374W | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRPF39 | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2
- PRUNE2 | c.6228G>T p.K2076N | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2
- QPRT | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2
- QRICH1 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | called by muse, varscan2
- RAB11FIP1 | c.1293C>A p.S431R | Missense Mutation (SNP) | VAF 76/1046 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2
- RADX | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAG1 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 19/539 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.202); called by muse, mutect2
- RAG1 | c.2482G>T p.E828* | Nonsense Mutation (SNP) | VAF 78/916 reads (9%) | called by muse, mutect2
- RBPJL | c.1182C>G p.S394R | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2
- RGPD3 | c.4327C>T p.H1443Y | Missense Mutation (SNP) | VAF 20/748 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2
- RGSL1 | c.1044T>G p.I348M | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- RLIM | c.126A>C p.E42D | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- ROBO4 | c.377G>C p.R126T | Missense Mutation (SNP) | VAF 34/584 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2
- RPA4 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 36/417 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- RPL10 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 68/832 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.238); called by muse, mutect2
- RPLP0 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 36/638 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.381); called by muse, mutect2
- RTL3 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- RYR2 | c.6721G>C p.D2241H | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RYR2 | c.13474C>G p.L4492V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); called by muse, mutect2
- RYR3 | c.3891C>A p.H1297Q | Missense Mutation (SNP) | VAF 19/306 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2
- SACS | c.12695G>A p.S4232N | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); called by muse, mutect2
- SETD1A | c.3623G>C p.R1208P | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SH2D2A | c.888C>A p.S296R | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2
- SH3BP4 | c.2289G>C p.M763I | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SIPA1 | c.2569G>T p.D857Y | Missense Mutation (SNP) | VAF 44/420 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SIPA1L1 | c.2959G>C p.G987R | Missense Mutation (SNP) | VAF 58/752 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC12A1 | c.701C>A p.A234E | Missense Mutation (SNP) | VAF 28/427 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- SLC13A5 | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SLC13A5 | c.386T>A p.M129K | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC22A15 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC22A18 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SLC2A6 | c.92+5G>C | Splice Region (SNP) | VAF 13/189 reads (7%) | called by muse, mutect2
- SLC4A8 | c.2652G>A p.M884I | Missense Mutation (SNP) | VAF 38/534 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.029); called by muse, mutect2
- SLC8A1 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SLC8A3 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- SLCO1C1 | c.1264T>A p.C422S | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- SLCO5A1 | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 40/475 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SORBS2 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 47/476 reads (10%) | called by muse, mutect2
- SOX7 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2
- SP2 | c.8-2A>G p.X3_splice | Splice Site (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- SPAM1 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 20/283 reads (7%) | called by muse, mutect2
- SPATA18 | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 25/330 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.092); called by muse, mutect2
- STAB2 | c.5413G>T p.D1805Y | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- STK32B | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNE2 | c.11768C>T p.P3923L | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.908); called by muse, mutect2
- SYNJ1 | c.3473G>C p.R1158P | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- TAP1 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 70/457 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- TAS1R2 | c.2426G>T p.G809V | Missense Mutation (SNP) | VAF 96/1146 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2
- TBL3 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- TCF7L2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- TEDC1 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2
- TEX13C | c.923C>G p.P308R | Missense Mutation (SNP) | VAF 40/628 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2
- TEX15 | c.7000T>A p.C2334S (on ENST00000256246; = p.C2717S on NM_001350162.2) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, varscan2
- TLE2 | c.600_601insA p.V201Sfs*19 | Frame Shift Ins (INS) | VAF 38/395 reads (10%) | called by mutect2, pindel, varscan2
- TMEM237 | c.904A>C p.N302H (on ENST00000409883 / NM_001044385.3; = p.N294H on NM_152388.4) | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.346); called by muse, mutect2
- TNS1 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 85/575 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNS3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.476); called by muse, mutect2
- TP53BP1 | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM69 | c.611C>T p.S204F (on ENST00000329464 / NM_182985.5; = p.S45F on NM_080745.5) | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- TTN | c.44610-8T>A | Splice Region (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- TTN | c.18818C>A p.T6273K (on ENST00000591111; = p.T5346K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | PolyPhen benign (0.027); called by muse, mutect2
- TUBGCP2 | c.98A>T p.Q33L | Missense Mutation (SNP) | VAF 39/511 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.028); called by muse, mutect2
- TUBGCP3 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2
- UBE2N | c.419-2A>T p.X140_splice | Splice Site (SNP) | VAF 22/236 reads (9%) | called by muse, mutect2
- UBL5 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 47/522 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- UMODL1 | c.2640C>A p.F880L (on ENST00000408910 / NM_001004416.2; = p.F1008L on NM_173568.3) | Missense Mutation (SNP) | VAF 32/532 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.012); called by muse, mutect2
- UNC119 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 60/929 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- USP51 | c.1654T>A p.C552S | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- VLDLR | c.1375A>T p.K459* | Nonsense Mutation (SNP) | VAF 40/392 reads (10%) | called by muse, mutect2
- VPS18 | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- VPS26A | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- WARS2 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- WFIKKN2 | c.1267G>A p.G423S | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.038); called by muse, mutect2
- WFS1 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 46/661 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WNT4 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.005); called by muse, mutect2
- XIRP2 | c.576G>T p.E192D (on ENST00000628543; = p.E367D on NM_152381.6) | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); called by muse, mutect2
- YLPM1 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 52/769 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZBTB20 | c.1306A>C p.S436R (on ENST00000474710 / NM_001164342.2; = p.S363R on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/522 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2
- ZEB1 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 59/739 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFHX4 | c.6160C>T p.P2054S | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.803); called by muse, mutect2
- ZNF112 | c.2504G>T p.C835F (on ENST00000337401 / NM_001083335.2; = p.C829F on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF263 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 43/359 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ZNF287 | c.508A>T p.M170L | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- ZNF699 | c.1789A>T p.S597C | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); called by muse, mutect2
- ZNF75D | c.753A>T p.L251F | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2
- ABCB7 | c.894T>C p.L298= (on ENST00000373394 / NM_001271696.3; = p.L299= on NM_004299.6) | Silent (SNP) | VAF 60/626 reads (10%) | called by muse, mutect2
- ABCG1 | c.843C>T p.F281= | Silent (SNP) | VAF 23/184 reads (13%) | catalogued as rs368376675; called by muse, mutect2, varscan2
- ACE | c.771C>T p.F257= | Silent (SNP) | VAF 68/733 reads (9%) | catalogued as rs780365048, COSV52014205; called by muse, mutect2
- ADH6 | c.735G>A p.Q245= | Silent (SNP) | VAF 30/473 reads (6%) | called by muse, mutect2
- AMH | c.915G>T p.P305= | Silent (SNP) | VAF 41/259 reads (16%) | called by muse, mutect2, varscan2
- ANGEL1 | c.558A>T p.A186= | Silent (SNP) | VAF 18/257 reads (7%) | called by muse, mutect2
- ANXA9 | c.354C>T p.D118= | Silent (SNP) | VAF 42/833 reads (5%) | catalogued as rs150030788; called by muse, mutect2
- AP1B1 | c.90G>A p.K30= | Silent (SNP) | VAF 16/402 reads (4%) | catalogued as rs1204902050; called by muse, mutect2
- ASTN2 | c.1554G>T p.T518= (on ENST00000313400 / NM_001365069.1; = p.T467= on NM_014010.5) | Silent (SNP) | VAF 15/200 reads (8%) | called by muse, mutect2
- BASP1 | c.279G>A p.A93= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1255906797; called by muse, mutect2, varscan2
- BORA | c.18C>T p.F6= | Silent (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- CA8 | c.480G>T p.P160= | Silent (SNP) | VAF 58/800 reads (7%) | catalogued as rs537454715; called by muse, mutect2
- CACNA1E | c.6498C>G p.P2166= (on ENST00000367573 / NM_001205293.3; = p.P2123= on NM_000721.4) | Silent (SNP) | VAF 34/422 reads (8%) | called by muse, mutect2
- CALHM3 | c.330C>T p.P110= | Silent (SNP) | VAF 49/457 reads (11%) | catalogued as COSV63921845; called by muse, mutect2, varscan2
- CARD14 | c.1842G>A p.Q614= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- CCDC74A | c.255C>T p.L85= | Silent (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- CD6 | c.1908C>A p.P636= | Silent (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- CD93 | c.213C>T p.H71= | Silent (SNP) | VAF 33/306 reads (11%) | catalogued as rs778708413, COSV55665211; called by muse, varscan2
- CIZ1 | c.892C>T p.L298= | Silent (SNP) | VAF 28/284 reads (10%) | catalogued as rs764751265; called by muse, mutect2, varscan2
- CLGN | c.1191C>T p.F397= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs76550209, COSV57773825; called by muse, mutect2, varscan2
- COL6A3 | c.1392C>A p.I464= | Silent (SNP) | VAF 30/321 reads (9%) | called by muse, mutect2
- CRIM1 | c.708G>A p.G236= | Silent (SNP) | VAF 35/539 reads (6%) | called by muse, mutect2
- DLGAP3 | c.1431G>T p.S477= | Silent (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2
- DMD | c.1629C>A p.I543= | Silent (SNP) | VAF 40/564 reads (7%) | called by muse, mutect2
- DPM3 | c.171G>A p.V57= (on ENST00000341298; = p.V87= on NM_018973.3) | Silent (SNP) | VAF 22/351 reads (6%) | catalogued as COSV100310423; called by muse, mutect2
- FERD3L | c.15G>T p.P5= | Silent (SNP) | VAF 6/68 reads (9%) | called by mutect2, varscan2
- FGF23 | c.216C>A p.A72= | Silent (SNP) | VAF 27/566 reads (5%) | called by muse, mutect2
- GABRQ | c.1284C>A p.T428= | Silent (SNP) | VAF 47/595 reads (8%) | called by muse, mutect2
- HCK | c.339G>A p.E113= | Silent (SNP) | VAF 24/280 reads (9%) | called by muse, mutect2
- HERC2 | c.3022C>T p.L1008= | Silent (SNP) | VAF 28/440 reads (6%) | catalogued as COSV55330895; called by muse, mutect2
- HSD17B3 | c.159C>T p.I53= | Silent (SNP) | VAF 66/828 reads (8%) | called by muse, mutect2
- IFRD2 | c.1134C>T p.A378= | Silent (SNP) | VAF 19/380 reads (5%) | catalogued as rs1553709114; called by muse, mutect2
- IGHV2-5 | c.60G>A p.Q20= | Silent (SNP) | VAF 64/870 reads (7%) | catalogued as rs782690310; called by muse, mutect2
- IGKV2D-30 | c.273G>A p.G91= | Silent (SNP) | VAF 83/1228 reads (7%) | called by muse, mutect2
- IKBKB | c.1008G>A p.L336= | Silent (SNP) | VAF 43/522 reads (8%) | catalogued as COSV60596548; called by muse, mutect2
- IKZF2 | c.252A>G p.L84= | Silent (SNP) | VAF 86/1229 reads (7%) | catalogued as COSV59580552; called by muse, mutect2
- IL16 | c.961C>T p.L321= | Silent (SNP) | VAF 54/658 reads (8%) | called by muse, mutect2
- IQGAP2 | c.4626G>A p.Q1542= | Silent (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- IRF2BP2 | c.573C>G p.L191= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV64015599; called by muse, mutect2
- ITIH5 | c.2599C>T p.L867= | Silent (SNP) | VAF 25/421 reads (6%) | called by muse, mutect2
- KCNA4 | c.429T>C p.S143= | Silent (SNP) | VAF 30/518 reads (6%) | catalogued as rs1310518601; called by muse, mutect2
- KCP | c.4128G>T p.L1376= (on ENST00000620378; = p.L1500= on NM_001366122.1) | Silent (SNP) | VAF 60/870 reads (7%) | called by muse, mutect2
- KLF4 | c.738G>T p.S246= | Silent (SNP) | VAF 27/326 reads (8%) | called by muse, mutect2
- LCE1C | c.183C>T p.G61= | Silent (SNP) | VAF 50/764 reads (7%) | called by muse, mutect2
- LRP1B | c.4066C>T p.L1356= | Silent (SNP) | VAF 56/491 reads (11%) | called by muse, mutect2, varscan2
- LRP4 | c.1992T>C p.N664= | Silent (SNP) | VAF 46/712 reads (6%) | called by muse, mutect2
- MAP7D3 | c.1602A>T p.P534= | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- MEPCE | c.840G>A p.E280= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV52769428; called by muse, mutect2, varscan2
- MKRN3 | c.573T>A p.A191= | Silent (SNP) | VAF 26/309 reads (8%) | called by muse, mutect2
- MPDZ | c.1026A>T p.T342= | Silent (SNP) | VAF 33/304 reads (11%) | called by muse, mutect2, varscan2
- MXRA5 | c.933C>T p.F311= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as COSV99479194; called by muse, mutect2
- MYF6 | c.468G>A p.K156= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as COSV57352601, COSV57353668; called by muse, mutect2
- MYH2 | c.5085G>T p.R1695= | Silent (SNP) | VAF 78/1114 reads (7%) | called by muse, mutect2
- NAP1L3 | c.660A>G p.E220= | Silent (SNP) | VAF 26/396 reads (7%) | called by muse, mutect2
- NAV1 | c.1884C>T p.L628= | Silent (SNP) | VAF 22/309 reads (7%) | called by muse, mutect2
- NEXMIF | c.1065G>T p.L355= | Silent (SNP) | VAF 18/430 reads (4%) | catalogued as COSV50032237; called by muse, mutect2
- NEXMIF | c.597G>T p.L199= | Silent (SNP) | VAF 24/256 reads (9%) | catalogued as COSV50044365; called by muse, mutect2
- NPFFR1 | c.837C>T p.F279= | Silent (SNP) | VAF 26/316 reads (8%) | called by muse, mutect2
- OR2L5 | c.546T>A p.A182= | Silent (SNP) | VAF 17/290 reads (6%) | catalogued as COSV62364753; called by muse, mutect2
- OR2T3 | c.357C>T p.L119= | Silent (SNP) | VAF 44/696 reads (6%) | catalogued as COSV62083183; called by muse, mutect2
- OR51A4 | c.570C>G p.A190= | Silent (SNP) | VAF 30/426 reads (7%) | called by muse, varscan2
- OR56A4 | c.663C>G p.L221= | Silent (SNP) | VAF 30/592 reads (5%) | called by muse, mutect2
- OR9K2 | c.510G>T p.V170= (on ENST00000305377; = p.V148= on NM_001005243.1) | Silent (SNP) | VAF 17/217 reads (8%) | called by muse, mutect2
- OR9Q2 | c.468C>A p.A156= | Silent (SNP) | VAF 40/624 reads (6%) | catalogued as rs374674373; called by muse, mutect2
- OXSM | c.1158G>T p.L386= | Silent (SNP) | VAF 22/360 reads (6%) | called by muse, mutect2
- PCDHA12 | c.786C>T p.I262= | Silent (SNP) | VAF 22/300 reads (7%) | called by muse, mutect2
- PCDHGA8 | c.807G>C p.P269= | Silent (SNP) | VAF 34/468 reads (7%) | called by muse, mutect2
- PEPD | c.408G>C p.L136= | Silent (SNP) | VAF 78/930 reads (8%) | called by muse, mutect2
- PKHD1L1 | c.3921T>C p.Y1307= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as rs1366462713; called by muse, mutect2
- PRAMEF14 | c.1233G>C p.T411= | Silent (SNP) | VAF 191/1430 reads (13%) | catalogued as rs747224136; called by muse, mutect2, varscan2
- PRX | c.4374T>G p.A1458= | Silent (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- PSKH2 | c.312G>A p.A104= | Silent (SNP) | VAF 56/909 reads (6%) | catalogued as rs569087166, COSV52612022; called by muse, mutect2
- RELN | c.1488G>C p.L496= | Silent (SNP) | VAF 22/323 reads (7%) | called by muse, mutect2
- RRBP1 | c.546G>T p.V182= | Silent (SNP) | VAF 21/250 reads (8%) | called by muse, mutect2
- RXFP2 | c.1422C>T p.F474= | Silent (SNP) | VAF 20/433 reads (5%) | catalogued as COSV53640978; called by muse, mutect2
- RYR2 | c.838C>T p.L280= | Silent (SNP) | VAF 37/310 reads (12%) | called by muse, mutect2, varscan2
- SCNN1D | c.1524C>G p.L508= (on ENST00000338555; = p.L672= on NM_001130413.4) | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- SDK2 | c.4404C>A p.P1468= | Silent (SNP) | VAF 100/361 reads (28%) | called by muse, mutect2, varscan2
- SDK2 | c.1617C>A p.G539= | Silent (SNP) | VAF 39/379 reads (10%) | catalogued as rs760588176; called by muse, mutect2
- SIGLEC8 | c.495A>G p.L165= | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- SLC22A4 | c.603C>T p.V201= | Silent (SNP) | VAF 68/979 reads (7%) | called by muse, mutect2
- SLC6A8 | c.156C>A p.R52= | Silent (SNP) | VAF 19/177 reads (11%) | catalogued as COSV53473489; called by muse, mutect2, varscan2
- SMARCA1 | c.1851A>T p.V617= | Silent (SNP) | VAF 15/216 reads (7%) | called by muse, mutect2
- SNRPN | c.60C>A p.I20= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as COSV57598389; called by muse, mutect2
- SOX14 | c.390G>T p.P130= | Silent (SNP) | VAF 18/237 reads (8%) | called by muse, mutect2
- SPAG6 | c.111G>A p.L37= | Silent (SNP) | VAF 41/514 reads (8%) | called by muse, mutect2
- SPEF2 | c.4581A>G p.T1527= | Silent (SNP) | VAF 20/374 reads (5%) | called by muse, mutect2
- SPTA1 | c.6969G>T p.L2323= | Silent (SNP) | VAF 66/898 reads (7%) | catalogued as COSV63754943; called by muse, mutect2
- TAS1R3 | c.1083G>A p.L361= | Silent (SNP) | VAF 21/194 reads (11%) | called by muse, mutect2, varscan2
- TEX10 | c.2244G>A p.Q748= | Silent (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- TG | c.5766C>T p.Y1922= | Silent (SNP) | VAF 42/670 reads (6%) | catalogued as CM160955; called by muse, mutect2
- THOC1 | c.505C>T p.L169= | Silent (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
- TMTC1 | c.2338C>T p.L780= (on ENST00000539277 / NM_001193451.2; = p.L672= on NM_175861.3) | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- TUBAL3 | c.1234C>T p.L412= | Silent (SNP) | VAF 48/324 reads (15%) | called by muse, mutect2, varscan2
- ULK2 | c.3087C>T p.L1029= | Silent (SNP) | VAF 30/462 reads (6%) | catalogued as rs1388517423, COSV64447718; called by muse, mutect2
- UNC119 | c.666G>T p.V222= | Silent (SNP) | VAF 60/918 reads (7%) | called by muse, mutect2
- VSIG1 | c.249C>T p.I83= | Silent (SNP) | VAF 28/440 reads (6%) | catalogued as rs770757067; called by muse, mutect2
- VSTM2A | c.201G>T p.R67= | Silent (SNP) | VAF 24/287 reads (8%) | called by muse, mutect2
- XIRP2 | c.5379T>C p.A1793= (on ENST00000628543; = p.A1968= on NM_152381.6) | Silent (SNP) | VAF 44/381 reads (12%) | catalogued as rs1167344561; called by muse, mutect2, varscan2
- ZIC4 | c.735C>T p.F245= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as rs1325919999, COSV67172232, COSV67173973; called by muse, mutect2
- ZNF445 | c.2664G>A p.R888= | Silent (SNP) | VAF 21/465 reads (5%) | called by muse, mutect2
- ZNF732 | c.9C>G p.L3= | Silent (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2
- ZNF804A | c.651A>T p.A217= | Silent (SNP) | VAF 40/576 reads (7%) | called by muse, mutect2
- ZNF850 | c.2016C>A p.P672= | Silent (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2
- AC244517.10 | c.36-10544A>C | Intron (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- AL353804.7 | chrX:73851134 G>T | 3'Flank (SNP) | VAF 46/728 reads (6%) | called by muse, mutect2
- AL353804.7 | chrX:73851135 G>T | 3'Flank (SNP) | VAF 47/734 reads (6%) | called by muse, mutect2
- ARHGAP23P1 | chr16:33938508 C>A | 5'Flank (SNP) | VAF 41/433 reads (9%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.1517+2199G>T | Intron (SNP) | VAF 37/535 reads (7%) | catalogued as COSV101182234; called by muse, mutect2
- B3GNTL1 | c.-7C>A | 5'UTR (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38567G>T | Intron (SNP) | VAF 49/361 reads (14%) | called by muse, mutect2, varscan2
- C2orf80 | c.-76+31G>A | Intron (SNP) | VAF 26/556 reads (5%) | called by muse, mutect2
- C4orf50 | c.-199del | 5'UTR (DEL) | VAF 22/204 reads (11%) | called by mutect2, varscan2
- CALCR | c.52-3341C>A | Intron (SNP) | VAF 17/226 reads (8%) | called by muse, mutect2
- CFL2 | c.*1739G>C | 3'UTR (SNP) | VAF 11/174 reads (6%) | catalogued as rs1433879552; called by muse, mutect2
- COL3A1 | c.*47G>A | 3'UTR (SNP) | VAF 28/156 reads (18%) | catalogued as COSV100483467; called by muse, varscan2
- DES | c.*49T>A | 3'UTR (SNP) | VAF 73/493 reads (15%) | called by muse, mutect2, varscan2
- DNAH3 | c.118-4212C>T | Intron (SNP) | VAF 25/238 reads (11%) | called by muse, mutect2, varscan2
- DNM3 | c.1689+7624G>T | Intron (SNP) | VAF 44/666 reads (7%) | catalogued as rs773909413; called by muse, mutect2
- ERVV-1 | chr19:53010477 C>A | 5'Flank (SNP) | VAF 38/610 reads (6%) | called by muse, mutect2
- FTCD | c.*2+70G>T | Intron (SNP) | VAF 23/251 reads (9%) | catalogued as COSV52430351; called by muse, mutect2
- GABRA6 | c.-25A>T | 5'UTR (SNP) | VAF 37/584 reads (6%) | called by muse, mutect2
- GCFC2 | c.1226+56T>G | Intron (SNP) | VAF 10/98 reads (10%) | called by muse, varscan2
- GPC1 | c.167-8222G>T | Intron (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- KCP | c.486+751C>A | Intron (SNP) | VAF 69/482 reads (14%) | called by muse, mutect2, varscan2
- KPNA2P3 | n.114G>A | RNA (SNP) | VAF 44/244 reads (18%) | called by muse, mutect2, varscan2
- KRT8P11 | n.866G>A | RNA (SNP) | VAF 31/366 reads (8%) | called by muse, mutect2
- MICAL3 | c.-75+43361G>T | Intron (SNP) | VAF 22/298 reads (7%) | called by muse, mutect2
- MIR92A2 | n.14G>T | RNA (SNP) | VAF 11/210 reads (5%) | called by muse, mutect2
- NBPF22P | n.653G>A | RNA (SNP) | VAF 30/614 reads (5%) | called by muse, mutect2
- NIPSNAP2 | c.278+1469C>T | Intron (SNP) | VAF 20/353 reads (6%) | called by muse, mutect2
- PDIA3P1 | chr1:147179467 C>G | 3'Flank (SNP) | VAF 53/592 reads (9%) | called by muse, mutect2
- PLA2G6 | c.797+26G>T | Intron (SNP) | VAF 18/154 reads (12%) | called by muse, varscan2
- POFUT2 | c.528-420G>T | Intron (SNP) | VAF 33/485 reads (7%) | called by muse, mutect2
- PRPH | c.870+30G>T | Intron (SNP) | VAF 27/263 reads (10%) | called by muse, mutect2, varscan2
- RELN | c.-14G>T | 5'UTR (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- RPL4 | c.-23C>T | 5'UTR (SNP) | VAF 26/336 reads (8%) | catalogued as rs146699571, COSV57179490; called by muse, mutect2
- SGCD | c.189+49151G>T | Intron (SNP) | VAF 26/358 reads (7%) | catalogued as rs954150850; called by muse, mutect2
- SLC35A2 | c.92-247A>G | Intron (SNP) | VAF 15/447 reads (3%) | called by muse, mutect2
- SLC41A3 | c.274-5476G>A | Intron (SNP) | VAF 17/188 reads (9%) | called by muse, mutect2
- SNORD116-26 | n.55G>T | RNA (SNP) | VAF 14/324 reads (4%) | called by muse, mutect2
- TBX15 | c.1025-5398C>G | Intron (SNP) | VAF 13/199 reads (7%) | called by muse, mutect2
- TEX45 | c.1207+184C>T | Intron (SNP) | VAF 18/162 reads (11%) | called by muse, varscan2
- TNFSF4 | c.153+1683G>T | Intron (SNP) | VAF 42/335 reads (13%) | called by muse, mutect2, varscan2
- TNFSF4 | c.153+1682G>T | Intron (SNP) | VAF 42/333 reads (13%) | called by muse, mutect2, varscan2
- TP63 | c.324+21C>T | Intron (SNP) | VAF 46/770 reads (6%) | called by muse, mutect2
- TRDV2 | chr14:22418439 C>A | 5'Flank (SNP) | VAF 14/334 reads (4%) | called by muse, mutect2
- TRHDE | chr12:72272098 C>T | 5'Flank (SNP) | VAF 38/392 reads (10%) | called by muse, mutect2
- TTC3P1 | n.5905C>A | RNA (SNP) | VAF 38/552 reads (7%) | called by muse, mutect2
- UNKL | chr16:1414723 C>T | 5'Flank (SNP) | VAF 13/81 reads (16%) | catalogued as rs773572503; called by muse, mutect2, varscan2
- UQCRB | c.*614G>T | 3'UTR (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- USP6 | c.1079-109G>A | Intron (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- USP6 | c.1079-108G>T | Intron (SNP) | VAF 16/299 reads (5%) | catalogued as rs1421268227; called by muse, mutect2
- Unknown | chr21:16194545 T>C | IGR (SNP) | VAF 14/257 reads (5%) | called by muse, mutect2
- XIST | n.10167G>T | RNA (SNP) | VAF 30/542 reads (6%) | called by muse, mutect2
- YY1AP1 | c.-21C>T | 5'UTR (SNP) | VAF 15/204 reads (7%) | catalogued as rs1360128497; called by muse, mutect2
- ZNF497 | c.-15+268G>T | Intron (SNP) | VAF 26/286 reads (9%) | called by muse, mutect2
- ZP2 | c.-8C>T | 5'UTR (SNP) | VAF 36/392 reads (9%) | catalogued as rs1458108102, COSV99559619; called by muse, mutect2
